Gene-level copy-number profile of tumor specimen HCM-BROD-0954-C34-01A from HCMI case HCM-BROD-0954-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 66.3 years (24,222 days).
Specimen HCM-BROD-0954-C34-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 616b6d66-6ffb-4136-b5c9-351852bd3196.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0954-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/1b75a3ee-7185-456a-8d62-afbbad3c3d4e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 21,537; copy number 2: 35,216; copy number 3: 875; copy number 4: 680; copy number 5: 42; copy number 6: 23.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:32,359,538–32,587,613, 16 genes (within-gene range 0–2): AC139426.2, DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3, AC135983.2, LINC02256, AC123768.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 65 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:121,451,541–121,451,967, 1 gene, copy number 5: TUBB4BP5.
- chr14:34,485,979–35,317,474, 32 genes, copy number 5–6 (within-gene range 4–6): RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3.
- chr14:52,791,756–52,930,185, 1 gene, copy number 5 (within-gene range 3–5): AL139317.5.
- chr14:52,857,268–52,952,864, 3 genes, copy number 5: FERMT2, AL139317.4, AL352979.4.
- chr14:54,938,949–55,962,970, 28 genes, copy number 5–6: WDHD1, RPSAP13, SOCS4, MAPK1IP1L, LGALS3, DLGAP5, AL139316.1, AL158801.4, COX5AP1, AL158801.2, FBXO34, AL158801.1, Metazoa_SRP, CHMP4BP1, AL158801.3, ATG14, HMGN1P1, TBPL2, RPL21P6, KTN1-AS1, RPL7AP4, ABI1P1, KTN1, Y_RNA, AL355773.1, RPL13AP3, LINC00520, AL163952.1.

Autosomal genes at a single copy (total copy number 1): 21,346. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
